Surgical pathology report (de-identified scan), TCGA case TCGA-B9-A5W9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-A5W9-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, papillary
renal cell 8260/3

Site: Kidney NOS
C64.9
QW 3/18/13

Diagnosis:

A: Kidney, right, partial nephrectomy

Procedure: partial nephrectomy

Laterality: right

Histologic tumor type/subtype: type I papillary renal cell carcinoma

Sarcomatoid features: absent

Histologic grade (if applicable): Grade 3

Tumor size (greatest dimension): 5.7 cm

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: absent

Gerota' s fascia: not applicable

Renal sinus: not applicable

Major veins (renal vein or segmental branches, IVC): not applicable

Ureter: not applicable

Venous (large vessel): not applicable

Lymphatic (small vessel): absent

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): negative

Renal capsular margin (partial nephrectomy only): negative

Paranephric adipose tissue margin (partial nephrectomy only): negative

Gerota' s fascia (nephrectomy): not applicable

Renal vein (nephrectomy): not applicable

Ureter (nephrectomy): not applicable

Adrenal gland: not submitted

Lymph nodes: not submitted

[page 2 of 3]
Pathologic findings in non-neoplastic kidney:

- Glomerulosclerosis
- Chronic interstitial inflammation

AJCC Staging:

pT1b

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

A portion of this case was reviewed in consultation with who concurs with the grade and stage of this tumor.

Clinical History:

-year-old male with right renal mass who presents for robotic partial right nephrectomy.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right renal mass." Requisition states "stitch marks closed collecting system." It holds an 89.8 gram, 6.5 x 5.2 x 4.3 cm partial nephrectomy. The parenchymal margin is tan/brown and inked black. Within the center of the parenchyma there is a stitch marking the closed collecting system, this area is inked red. The capsule is tan/yellow, intact, bulges and is inked blue. Beneath the bulging capsule there is a 5.7 x 5.3 x 3.6 cm tan/brown firm, well circumscribed mass with areas of hemorrhage adjacent to the capsule. The mass is abutting the red inked stitched area designated by the surgeon as a closed collecting system, is 0.4 cm from the black inked parenchymal margin, and bulges but does not extend through the capsule. The uninvolved renal parenchyma is tan/brown with a distinct corticomedullary junction. A representative section of the mass is submitted to Tissue Procurement.

Block summary:

A1-A2 - mass with respect to red inked closed collecting system, perpendicular

A3-A4 - mass with respect to black inked parenchymal margin, perpendicular

[page 3 of 3]
A5-A6 - mass with respect to capsule, perpendicular
A7 - uninvolved kidney parenchyma away from mass
Tissue remains in formalin.

Source: NCI Genomic Data Commons file a2571dec-a908-4e32-81ec-1e46af8740b5 (TCGA-B9-A5W9.4713327E-50FF-4B7F-8F7F-1D024420C840.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).